Somatic mutation profile of tumor specimen TCGA-AC-A23G-01A (aliquot TCGA-AC-A23G-01A-11D-A20S-09) from TCGA case TCGA-AC-A23G, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.5 years (27,934 days).
Specimen TCGA-AC-A23G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 605fd20e-aa4f-44c5-8867-e1a3c09186f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A23G-11A (Solid Tissue Normal), aliquot TCGA-AC-A23G-11A-12D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03a7baf1-efb0-415a-8c42-c7a2c8cd5b54

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 2, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD12 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as COSV59288500; called by muse, mutect2, varscan2
- ARHGAP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs78337553, COSV61533654; called by muse, mutect2, varscan2
- C8orf33 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as COSV58896074; called by muse, mutect2, varscan2
- CDH1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV55729448; called by muse, mutect2, varscan2
- CHST7 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52099700; called by muse, mutect2
- ESPL1 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV57762654; called by muse, mutect2, varscan2
- GRIA3 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV52049681; called by muse, mutect2, varscan2
- GRIA3 | c.2662G>A p.G888R | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52047746, COSV52077566; called by muse, mutect2
- LRRK2 | c.1307T>A p.L436Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54167828; called by muse, mutect2, varscan2
- OASL | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57478350, COSV57480247; called by muse, mutect2, varscan2
- OR2J3 | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV65849595; called by muse, mutect2, varscan2
- PIK3R3 | c.931del p.Q311Nfs*11 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | catalogued as COSV53109194; called by mutect2, pindel
- PLXNA1 | c.3751G>A p.G1251R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV52531700; called by muse, mutect2, varscan2
- RABGAP1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV100438669; called by muse, mutect2, varscan2
- REG1B | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV59307586; called by mutect2, varscan2
- TCEAL8 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100749840; called by muse, mutect2
- TENM2 | c.1684A>T p.M562L (on ENST00000518659 / NM_001122679.2; = p.M330L on NM_001080428.3) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV69139329; called by muse, mutect2, varscan2
- AP002748.5 | c.1412_1426del p.Y471_T475del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- MUC4 | c.1628_1655del p.G543Afs*35 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel
- PCDHA9 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF8 | c.901A>T p.I301F (on ENST00000357988 / NM_001184896.1; = p.I265F on NM_015107.3) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- PYCR1 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR72 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.115); called by muse, mutect2
- COLGALT1 | c.1023C>T p.D341= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs145927102, COSV53111292; called by muse, mutect2, varscan2
- DMD | c.4377A>T p.R1459= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV63785816; called by muse, mutect2, varscan2
- FN3K | c.459C>T p.F153= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV56182998; called by muse, mutect2, varscan2
- KMT2E | c.5172C>T p.S1724= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV57578716; called by muse, mutect2, varscan2
- PDE1C | c.1467G>A p.E489= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1455810033, COSV58518366, COSV58526069; called by muse, mutect2, varscan2
- PDE7A | c.129G>A p.Q43= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV67524632; called by muse, mutect2, varscan2
- TSC22D1 | c.198G>T p.P66= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs370534959; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2559+49C>T | Intron (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- BSDC1 | c.190-13G>C | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as COSV61983136; called by muse, mutect2, varscan2
